Somatic mutation profile of tumor specimen TCGA-AA-A01C-01A (aliquot TCGA-AA-A01C-01A-01W-A00E-09) from TCGA case TCGA-AA-A01C, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.9 years (27,729 days).
Specimen TCGA-AA-A01C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c54a719-cac2-49c9-ad6d-0c8900442f34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01C-10A (Blood Derived Normal), aliquot TCGA-AA-A01C-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c1a921f-ee1b-4647-859f-4d1d56d97192

The open-access MAF lists 83 somatic variants for this specimen: 65 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 16, Nonsense Mutation 3, Frame Shift Del 3, RNA 2, Frame Shift Ins 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 21/36 reads (58%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 19/113 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS5 | c.1997A>T p.K666M | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99537135; called by muse, mutect2, varscan2
- ADGRL3 | c.1495G>A p.G499R (on ENST00000506720 / NM_001322402.2; = p.G431R on NM_015236.6) | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.223); catalogued as COSV101546899, COSV72232130; called by muse, mutect2
- AJAP1 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65449069; called by muse, mutect2, varscan2
- ANO4 | c.2236C>T p.R746* (on ENST00000392977 / NM_001286615.2; = p.R711* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 31/187 reads (17%) | catalogued as COSV54606613; called by muse, mutect2, varscan2
- C12orf4 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV99712594; called by muse, mutect2, varscan2
- CENPC | c.1514A>G p.K505R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99893609; called by muse, mutect2, varscan2
- CENPE | c.8032G>A p.E2678K | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54378239, COSV99477176; called by muse, mutect2
- CFAP70 | c.1973A>T p.Y658F | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.412); catalogued as COSV100160246; called by muse, mutect2, varscan2
- CHN1 | c.548G>A p.R183K | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1396916213, COSV101303529; called by muse, mutect2
- CIDEA | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs372248989, COSV100254917; called by muse, mutect2, varscan2
- CNTNAP4 | c.3244T>G p.L1082V | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56666193, COSV56691246; called by muse, mutect2, varscan2
- CTNND2 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs201021638, COSV58918848; called by muse, mutect2
- DCLRE1B | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99870610; called by muse, mutect2, varscan2
- FAT3 | c.3730G>C p.V1244L | Missense Mutation (SNP) | VAF 43/836 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV53079067; called by muse, mutect2
- GOLGB1 | c.6446G>A p.R2149H | Missense Mutation (SNP) | VAF 331/848 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs563428325, COSV100510403; called by muse, mutect2, varscan2
- H3C2 | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV52518439, COSV52519759; called by muse, mutect2, varscan2
- HNRNPAB | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as COSV57424248; called by muse, mutect2, varscan2
- ICE1 | c.1811T>C p.L604S | Missense Mutation (SNP) | VAF 10/336 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1561088022, COSV99663960; called by muse, mutect2
- IKBKB | c.773C>A p.S258Y | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100645607; called by muse, mutect2
- IL1RAP | c.1567G>T p.V523F | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.02); catalogued as COSV50771673, COSV99299141; called by muse, mutect2, varscan2
- JAKMIP2 | c.2326C>A p.L776I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV99507568; called by muse, mutect2, varscan2
- JMJD1C | c.7270A>G p.I2424V | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs773110764, COSV100550194; called by muse, mutect2, varscan2
- KCNH7 | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 14/337 reads (4%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.67); catalogued as COSV100034418, COSV59811796; called by muse, mutect2
- KCNMB1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.518); catalogued as rs199779409, COSV51133815; called by muse, mutect2, varscan2
- KHDC3L | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as COSV64869661; called by muse, mutect2, varscan2
- KIF21A | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100735334; called by muse, mutect2
- LONRF2 | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV101110865; called by muse, mutect2, varscan2
- LRRC10 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs768421373, COSV100825446, COSV64060146; called by muse, mutect2, varscan2
- MAPRE2 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV55817566, COSV55818342; called by muse, varscan2
- MRPL46 | c.605C>G p.A202G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV56899319; called by muse, mutect2
- NEFM | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs368542205; called by mutect2, varscan2
- NEXMIF | c.3190C>T p.R1064C | Missense Mutation (SNP) | VAF 173/231 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195044913, COSV50032739; called by muse, mutect2, varscan2
- OLFM4 | c.66G>T p.L22F | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.202); catalogued as COSV99524208; called by muse, mutect2
- OR1C1 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs539224501, COSV68715493; called by muse, mutect2, varscan2
- PCDHB2 | c.1195G>C p.V399L | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV99164280; called by muse, mutect2, varscan2
- PDK1 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV99961149; called by muse, mutect2
- PHF14 | c.1235T>A p.V412D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV101301777; called by muse, mutect2
- POLG2 | c.1295A>T p.Y432F | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV73376851; called by muse, mutect2, varscan2
- PRRC2C | c.4496A>T p.E1499V (on ENST00000367742; = p.E1497V on NM_015172.4) | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100144779; called by muse, mutect2, varscan2
- RAD52 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57273797; called by muse, mutect2, varscan2
- RASL11B | c.644G>A p.R215K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99954387; called by muse, mutect2, varscan2
- RBPJL | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100643447; called by muse, mutect2, varscan2
- RHOJ | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1299232020, COSV57456400; called by muse, mutect2, varscan2
- SCAI | c.949A>G p.K317E (on ENST00000336505 / NM_001144877.3; = p.K340E on NM_173690.5) | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.973); catalogued as COSV60618731; called by muse, mutect2
- SETDB1 | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1200589286, COSV99643913; called by muse, mutect2, varscan2
- SLC45A2 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.166); catalogued as rs145071815, COSV99672401; called by muse, mutect2, varscan2
- SYNE1 | c.5414G>A p.R1805Q (on ENST00000367255 / NM_182961.4; = p.R1812Q on NM_033071.3) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs749200824, COSV55074337; called by muse, mutect2, varscan2
- SZT2 | c.1975G>T p.A659S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV100986948; called by muse, mutect2
- TAF2 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 122/698 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as COSV100978477; called by muse, mutect2, varscan2
- TET1 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs760283652, COSV65390630; called by muse, mutect2, varscan2
- TP53 | c.370del p.C124Afs*46 | Frame Shift Del (DEL) | VAF 67/152 reads (44%) | catalogued as COSV52680549, COSV52752618; called by mutect2, pindel, varscan2
- TRAK1 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774718665, COSV59639544; called by muse, mutect2, varscan2
- XAGE3 | c.188-1G>C p.X63_splice | Splice Site (SNP) | VAF 41/176 reads (23%) | catalogued as COSV100655635; called by muse, mutect2, varscan2
- ZBTB26 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101021017, COSV101021118; called by muse, mutect2
- ZNF208 | c.1891C>A p.H631N | Missense Mutation (SNP) | VAF 30/728 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV68101066, COSV68107142; called by muse, mutect2
- ZNF423 | c.709C>T p.R237C (on ENST00000563137 / NM_001379286.1; = p.R229C on NM_015069.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52177905; called by muse, mutect2, varscan2
- ZNF556 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs146297141, COSV56911178; called by muse, mutect2, varscan2
- ZNF585A | c.615G>C p.Q205H (on ENST00000292841 / NM_001288800.2; = p.Q150H on NM_152655.3) | Missense Mutation (SNP) | VAF 94/686 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99492809; called by muse, mutect2
- ABCA13 | c.11565_11587del p.K3855Nfs*139 | Frame Shift Del (DEL) | VAF 29/110 reads (26%) | called by mutect2, pindel, varscan2
- ECSIT | c.249_254del p.E83_R84del | In Frame Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- KMT2E | c.679del p.R227Efs*77 | Frame Shift Del (DEL) | VAF 37/325 reads (11%) | called by mutect2, pindel, varscan2
- RGMB | c.1177dup p.E393Gfs*29 (on ENST00000513185 / NM_001366508.1; = p.E434Gfs*29 on NM_001012761.3 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 20/41 reads (49%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.562dup p.T188Nfs*12 | Frame Shift Ins (INS) | VAF 205/871 reads (24%) | called by mutect2, pindel, varscan2
- AASDHPPT | c.798G>A p.Q266= | Silent (SNP) | VAF 11/216 reads (5%) | catalogued as COSV53788311; called by muse, mutect2
- AK7 | c.2103C>T p.N701= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs961832991, COSV99967041; called by muse, mutect2, varscan2
- AKAP11 | c.1293G>A p.P431= | Silent (SNP) | VAF 59/633 reads (9%) | catalogued as rs139837011, COSV50296024; called by muse, mutect2
- AL592490.1 | c.2310C>T p.V770= | Silent (SNP) | VAF 95/233 reads (41%) | catalogued as rs1377692065, COSV69424694; called by muse, mutect2, varscan2
- BUB1B | c.2890T>C p.L964= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99806629; called by muse, mutect2, varscan2
- CATSPER2 | c.1068G>A p.A356= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs759288619, COSV58660257; called by muse, mutect2, varscan2
- CTNNA1 | c.1338T>C p.G446= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100242262; called by muse, mutect2
- DNAH9 | c.8028C>A p.I2676= | Silent (SNP) | VAF 13/243 reads (5%) | catalogued as COSV99304520; called by muse, mutect2
- DYNC1H1 | c.1977G>A p.T659= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as rs151170554; called by muse, mutect2, varscan2
- GRM2 | c.2133C>T p.P711= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs201665578, COSV99622511; called by muse, mutect2, varscan2
- IGHV3-66 | c.171C>A p.R57= | Silent (SNP) | VAF 13/329 reads (4%) | called by muse, mutect2
- MTNR1A | c.273C>T p.N91= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs377059126; called by muse, mutect2, varscan2
- OR10W1 | c.219G>A p.L73= | Silent (SNP) | VAF 10/192 reads (5%) | catalogued as COSV101223621; called by muse, mutect2
- PRKDC | c.3807G>A p.T1269= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs913376685, COSV58043881; called by muse, mutect2, varscan2
- PTPN9 | c.1638G>A p.T546= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs371391546; called by muse, mutect2, varscan2
- ZNF84 | c.1821T>G p.A607= | Silent (SNP) | VAF 95/266 reads (36%) | called by muse, mutect2, varscan2
- ISCA1P1 | n.230T>C | RNA (SNP) | VAF 56/227 reads (25%) | called by muse, mutect2, varscan2
- SNORD116-2 | n.71G>A | RNA (SNP) | VAF 16/82 reads (20%) | catalogued as rs1167604737; called by muse, mutect2, varscan2
